Somatic mutation profile of tumor specimen ALCH-AEBL-TTP1-A (aliquot ALCH-AEBL-TTP1-A-1-0-D-A605-36) from ALCHEMIST case ALCH-AEBL, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 75.6 years (27,627 days).
Specimen ALCH-AEBL-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c5e598d-0240-411d-9746-cc0e16bcbd12.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEBL-NB1-A (Blood Derived Normal), aliquot ALCH-AEBL-NB1-A-1-0-D-A605-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d512abd3-ee7e-4519-b7e9-221fbf9f4f91

The open-access MAF lists 64 somatic variants for this specimen: 36 protein-altering or splice-affecting, 20 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 20, Intron 4, 3'UTR 4, Nonsense Mutation 2, Splice Region 2, Frame Shift Del 1, In Frame Del 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD35 | c.1528C>T p.R510W | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs782531359; called by muse, mutect2, varscan2
- C7 | c.2080C>T p.P694S | Missense Mutation (SNP) | VAF 20/201 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.017); catalogued as COSV57474147; called by muse, mutect2
- CCR2 | c.850G>C p.D284H | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.501); catalogued as COSV52748232, COSV52749827; called by muse, mutect2, varscan2
- CGNL1 | c.1840G>A p.E614K | Missense Mutation (SNP) | VAF 15/176 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.423); catalogued as COSV55575187; called by muse, mutect2
- COL6A1 | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 64/544 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs145838277; called by muse, mutect2, varscan2
- DDX42 | c.1219G>C p.D407H | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63789836; called by muse, mutect2, varscan2
- DNMBP | c.625G>C p.D209H | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as COSV60633548; called by muse, mutect2
- EGFR | c.2237_2255delinsT p.E746_S752delinsV | In Frame Del (DEL) | VAF 104/672 reads (15%) | catalogued as rs727504258, COSV51765862; ClinVar: drug response; called by pindel, varscan2*
- FFAR4 | c.554C>G p.P185R | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.549); catalogued as rs1219203267; called by muse, mutect2
- PPP1R3D | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.471); catalogued as COSV62565028; called by muse, mutect2, varscan2
- RBCK1 | c.1438C>T p.R480C (on ENST00000356286 / NM_031229.4; = p.R438C on NM_006462.6) | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1436848446, COSV62293602; called by muse, mutect2, varscan2
- SETDB1 | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 81/431 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs755239027; called by muse, mutect2, varscan2
- SSRP1 | c.1698G>C p.K566N | Missense Mutation (SNP) | VAF 26/324 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as COSV53481953; called by muse, mutect2
- ZEB2 | c.3280G>A p.E1094K | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV57953550, COSV57956836; called by muse, mutect2
- ZNF80 | c.157G>C p.E53Q | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.177); catalogued as COSV100352108; called by muse, mutect2
- BCAR1 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- CERS3 | c.609+3_609+6del | Splice Region (DEL) | VAF 8/67 reads (12%) | called by mutect2, pindel
- DENND2B | c.3166C>T p.Q1056* | Nonsense Mutation (SNP) | VAF 56/541 reads (10%) | called by muse, mutect2, varscan2
- DUSP15 | c.196G>C p.E66Q (on ENST00000278979 / NM_001320479.1; = p.E69Q on NM_080611.4) | Missense Mutation (SNP) | VAF 51/303 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- EPHA3 | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ETV3 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 24/296 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2
- GBA3 | c.302A>G p.N101S | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.062); called by muse, mutect2
- GLI4 | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- GNMT | c.819C>G p.F273L | Missense Mutation (SNP) | VAF 41/473 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.464); called by muse, mutect2
- GOLGA3 | c.1825C>G p.L609V | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HRNR | c.2318G>A p.G773D | Missense Mutation (SNP) | VAF 41/702 reads (6%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.888); called by muse, mutect2
- IDH3B | c.1071+8G>A | Splice Region (SNP) | VAF 86/537 reads (16%) | called by muse, mutect2, varscan2
- MSANTD2 | c.1039G>C p.E347Q (on ENST00000374979 / NM_001308027.2; = p.E295Q on NM_024631.4) | Missense Mutation (SNP) | VAF 93/274 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PCDHB8 | c.2251C>T p.Q751* | Nonsense Mutation (SNP) | VAF 52/398 reads (13%) | called by muse, mutect2, varscan2
- PHF8 | c.2089G>A p.E697K (on ENST00000357988 / NM_001184896.1; = p.E661K on NM_015107.3) | Missense Mutation (SNP) | VAF 26/181 reads (14%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- PITRM1 | c.2969G>A p.R990K | Missense Mutation (SNP) | VAF 27/258 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RNPEP | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 27/298 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SETDB1 | c.956del p.K319Rfs*6 | Frame Shift Del (DEL) | VAF 42/178 reads (24%) | called by mutect2, pindel, varscan2
- SLC13A1 | c.1241T>C p.V414A | Missense Mutation (SNP) | VAF 55/258 reads (21%) | SIFT tolerated (0.86); PolyPhen benign (0.122); called by muse, varscan2
- TMEM45B | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 47/166 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UEVLD | c.1414T>A p.*472Rext*6 | Nonstop Mutation (SNP) | VAF 10/61 reads (16%) | called by muse, varscan2
- AC011479.1 | c.99G>A p.R33= | Silent (SNP) | VAF 40/392 reads (10%) | called by muse, mutect2, varscan2
- ASXL1 | c.3054T>A p.T1018= | Silent (SNP) | VAF 25/165 reads (15%) | called by muse, mutect2, varscan2
- BMP15 | c.147A>G p.L49= | Silent (SNP) | VAF 32/209 reads (15%) | called by muse, mutect2, varscan2
- BTN2A1 | c.678C>T p.L226= | Silent (SNP) | VAF 17/138 reads (12%) | catalogued as rs535843474, COSV57002834; called by muse, mutect2, varscan2
- CDH2 | c.1275A>G p.G425= | Silent (SNP) | VAF 20/232 reads (9%) | called by muse, mutect2
- CENATAC | c.921A>T p.G307= | Silent (SNP) | VAF 19/171 reads (11%) | called by muse, mutect2, varscan2
- CLDN5 | c.591C>T p.P197= (on ENST00000618236 / NM_001363066.2; = p.P282= on NM_003277.4) | Silent (SNP) | VAF 12/152 reads (8%) | catalogued as COSV54245283; called by muse, mutect2
- CRYBG3 | c.6069T>C p.S2023= | Silent (SNP) | VAF 26/168 reads (15%) | called by muse, mutect2, varscan2
- DOK7 | c.762G>A p.P254= | Silent (SNP) | VAF 32/170 reads (19%) | catalogued as rs763623892, COSV100403686; ClinVar: likely benign; called by muse, mutect2, varscan2
- GP5 | c.699C>T p.I233= | Silent (SNP) | VAF 32/224 reads (14%) | called by muse, mutect2, varscan2
- MUC5B | c.9594C>T p.S3198= | Silent (SNP) | VAF 32/390 reads (8%) | catalogued as rs1272576333; called by muse, mutect2
- NUDT13 | c.930G>A p.K310= | Silent (SNP) | VAF 36/504 reads (7%) | catalogued as COSV61970315; called by muse, mutect2
- RBM20 | c.3264C>T p.P1088= | Silent (SNP) | VAF 90/564 reads (16%) | called by muse, mutect2, varscan2
- REC114 | c.42C>T p.T14= | Silent (SNP) | VAF 19/142 reads (13%) | catalogued as rs540205218; called by muse, mutect2, varscan2
- SALL1 | c.2940C>A p.I980= | Silent (SNP) | VAF 147/686 reads (21%) | catalogued as COSV51760448; called by muse, mutect2, varscan2
- SPRYD3 | c.360T>A p.A120= | Silent (SNP) | VAF 34/169 reads (20%) | called by muse, mutect2, varscan2
- SULT1E1 | c.732C>T p.D244= | Silent (SNP) | VAF 37/539 reads (7%) | catalogued as rs546191623, COSV99895119; called by muse, mutect2
- UNC93B1 | c.1257C>G p.L419= | Silent (SNP) | VAF 18/250 reads (7%) | called by muse, mutect2
- ZNF335 | c.1300C>T p.L434= | Silent (SNP) | VAF 31/153 reads (20%) | called by muse, mutect2, varscan2
- ZSCAN1 | c.177C>T p.L59= | Silent (SNP) | VAF 19/141 reads (13%) | called by muse, mutect2, varscan2
- ACACA | c.*24C>T | 3'UTR (SNP) | VAF 39/314 reads (12%) | called by muse, mutect2, varscan2
- ACAP3 | c.47+695C>G | Intron (SNP) | VAF 13/185 reads (7%) | called by muse, mutect2
- ADM2 | c.*272G>A | 3'UTR (SNP) | VAF 19/168 reads (11%) | catalogued as rs930027501; called by muse, mutect2, varscan2
- CSNK1G3 | c.*3C>G | 3'UTR (SNP) | VAF 23/339 reads (7%) | catalogued as rs764340855, COSV100631280; called by muse, mutect2
- DDX41 | c.*575G>A | 3'UTR (SNP) | VAF 39/252 reads (15%) | called by muse, mutect2, varscan2
- HNF4G | c.-23-3773A>G | Intron (SNP) | VAF 24/240 reads (10%) | catalogued as COSV100584496; called by muse, mutect2, varscan2
- IDH3B | c.666-28G>C | Intron (SNP) | VAF 115/752 reads (15%) | called by muse, mutect2, varscan2
- NFS1 | c.409-1766C>A | Intron (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
